TCGA case TCGA-HB-A3YV — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Kidney; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/109df703-2865-4b4c-8e4b-badff8eb3f22

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 139 days.

Diagnoses (1)
1. Giant cell sarcoma: ICD-O-3 morphology code: 8802/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 75.5 years (27,583 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Contiguous organ invaded: Adrenal; Sites of involvement: Adrenal gland, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 14.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.

Follow-up (1 entry)
- Days to follow up: 139 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 21.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HB-A3YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 690 mg.
  Slide TCGA-HB-A3YV-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HB-A3YV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HB-A3YV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ resection: Adrenal gland; Contiguous organ invaded: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Kidney.
- Radiation treatment: Days from index date to radiation therapy started: 93; Days from index date to radiation therapy ended: 128; Radiation therapy type: External; Radiation total dose: 4500; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 25; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 139 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 139 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 139 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HB-A3YV-01A-11D-A24M-01): tumor purity 0.88, ploidy 3.5, whole-genome doublings 1.
